Somatic mutation profile of tumor specimen TCGA-D5-6920-01A (aliquot TCGA-D5-6920-01A-11D-1924-10) from TCGA case TCGA-D5-6920, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.0 years (28,124 days).
Specimen TCGA-D5-6920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d98cb210-24c6-4df8-ae16-ea14cfec998b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6920-10A (Blood Derived Normal), aliquot TCGA-D5-6920-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04ecc827-2290-4d51-8368-394ead7c0e37

The open-access MAF lists 122 somatic variants for this specimen: 93 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 28, Nonsense Mutation 8, Frame Shift Del 6, Frame Shift Ins 1, In Frame Ins 1, Translation Start Site 1, Splice Site 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 40/218 reads (18%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 42/283 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC3 | c.3410A>G p.K1137R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); catalogued as COSV99559005; called by muse, varscan2
- ADAMTS13 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs281875340, CM040366, COSV52469773; ClinVar: not provided; called by muse, mutect2, varscan2
- ANK3 | c.6262A>G p.T2088A | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV55055941; called by muse, mutect2, varscan2
- ASXL2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1559535727, COSV55458130, COSV55467017; called by muse, mutect2, varscan2
- BBS2 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs768699088, COSV55326203; called by muse, mutect2, varscan2
- BTNL9 | c.176G>A p.C59Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59795576; called by muse, mutect2, varscan2
- C2orf78 | c.2426C>T p.A809V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs764499050, COSV68517433; called by muse, mutect2, varscan2
- CD163 | c.3348T>A p.N1116K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV63131861; called by muse, mutect2, varscan2
- CDR1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs139383933, COSV65163954; called by muse, mutect2, varscan2
- CLCC1 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.182); catalogued as COSV56763270; called by muse, mutect2, varscan2
- CLCNKB | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs368764495, COSV100989727; called by muse, mutect2, varscan2
- COL19A1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754662807, COSV59571613; called by muse, mutect2, varscan2
- COL6A3 | c.9384G>A p.W3128* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as rs1405374416, COSV55087910; called by muse, mutect2, varscan2
- COQ4 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs774395996, CM150820, COSV55956988, COSV55957022; called by muse, mutect2, varscan2
- DSC1 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57145208, COSV57149539; called by muse, mutect2, varscan2
- E4F1 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs909522340, COSV100065608; called by muse, mutect2
- EHMT1 | c.3085G>A p.V1029M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs886613648, COSV71777807; called by muse, mutect2, varscan2
- ELAVL2 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV56361180; called by muse, mutect2, varscan2
- ENPP3 | c.1007C>A p.A336D | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV62954080; called by muse, mutect2, varscan2
- EPB41L5 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV55351702; called by muse, mutect2, varscan2
- ERCC3 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.131); catalogued as rs139690693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESPNL | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs763797257, COSV58032222; called by muse, mutect2, varscan2
- FAT4 | c.11424T>A p.C3808* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV58682510; called by muse, mutect2
- FES | c.1596C>A p.S532R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV60998023; called by muse, mutect2, varscan2
- FKBP10 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs371079363; called by muse, mutect2, varscan2
- FLNB | c.1425C>G p.F475L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV55878246; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.430A>T p.R144* | Nonsense Mutation (SNP) | VAF 65/325 reads (20%) | catalogued as COSV100436307; called by muse, mutect2, varscan2
- GABRA5 | c.131A>T p.D44V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV59479031; called by muse, mutect2, varscan2
- GALNT14 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs199694822, COSV61104711; called by muse, mutect2, varscan2
- GIGYF2 | c.1348A>G p.I450V | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV65248831; called by muse, mutect2, varscan2
- GRID2 | c.254T>A p.L85H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56200177; called by muse, mutect2, varscan2
- GRIN2B | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as rs750935831, COSV74205741; called by muse, mutect2, varscan2
- HEATR4 | c.2561C>T p.T854I | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV100408012; called by muse, mutect2, varscan2
- IGSF10 | c.4147G>A p.E1383K | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs372469513; called by muse, mutect2, varscan2
- IPO8 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as COSV99805132; called by muse, mutect2
- IRAG1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as COSV101351098; called by muse, mutect2
- IRF2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66928684, COSV66929319; called by muse, mutect2, varscan2
- ISG15 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as COSV65106509; called by muse, mutect2, varscan2
- JMY | c.2033G>A p.R678K | Missense Mutation (SNP) | VAF 82/471 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101267994; called by muse, mutect2, varscan2
- KLKB1 | c.1777G>T p.V593L | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749475483, COSV99249839; called by muse, mutect2, varscan2
- MAP3K11 | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs1409843441, COSV58419459; called by muse, mutect2, varscan2
- MED12L | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777002012, COSV56372488; called by muse, mutect2, varscan2
- MGA | c.7746A>G p.E2582= (on ENST00000219905 / NM_001164273.1; = p.E2373= on NM_001080541.2) | Splice Region (SNP) | VAF 31/111 reads (28%) | catalogued as COSV54953049; called by muse, mutect2, varscan2
- MXRA5 | c.6569C>T p.A2190V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as rs756980812, COSV54233487; called by muse, mutect2, varscan2
- NLRP14 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55066586; called by muse, mutect2, varscan2
- NR2C2 | c.817G>A p.A273T (on ENST00000393102; = p.A292T on NM_003298.5) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1357686163, COSV60146122; called by muse, mutect2, varscan2
- NRXN2 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs373695786; called by muse, mutect2, varscan2
- OR10H5 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs368159341; called by muse, mutect2, varscan2
- OR2H1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV65810606; called by muse, mutect2, varscan2
- OR4C15 | c.685C>A p.H229N (on ENST00000314644; = p.H175N on NM_001001920.2) | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as COSV58952556, COSV58956358; called by muse, mutect2, varscan2
- OR6C68 | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV65563004, COSV65563188; called by muse, mutect2, varscan2
- OR6K2 | c.934T>C p.F312L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV62743408, COSV62744170; called by muse, mutect2, varscan2
- PAPPA2 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs771937888, COSV62796581; called by muse, mutect2, varscan2
- PCBP4 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs746354848, COSV59054483; called by muse, mutect2, varscan2
- PCNX2 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV50797485; called by muse, mutect2, varscan2
- PIAS4 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1344058915, COSV53678957; called by muse, mutect2
- PKHD1L1 | c.557T>A p.V186D | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.383); catalogued as COSV65742109; called by muse, mutect2, varscan2
- POTEF | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs776009831; called by muse, mutect2
- PSG7 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs184944789, COSV68445003; called by muse, mutect2, varscan2
- RDX | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1030064754, COSV58193193; called by muse, mutect2, varscan2
- RPA1 | c.1177G>T p.V393L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV54609165, COSV54613342; called by muse, mutect2, varscan2
- SEPTIN2 | c.594G>T p.R198S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV63472088; called by muse, mutect2, varscan2
- SERINC1 | c.851-1G>C p.X284_splice | Splice Site (SNP) | VAF 10/95 reads (11%) | catalogued as COSV60101969; called by muse, mutect2
- SH2D3C | c.1234G>A p.E412K (on ENST00000314830 / NM_170600.3; = p.E255K on NM_005489.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.089); catalogued as rs774083450, COSV59124455; called by muse, mutect2, varscan2
- SHMT1 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100363521; called by muse, mutect2
- SIX1 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as rs1051653507, COSV55959790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC7A11 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs186693425, COSV54928631, COSV54929311; called by muse, mutect2, varscan2
- SMTN | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs746764891, COSV60777718; called by muse, mutect2, varscan2
- TENT5A | c.1222G>C p.A408P | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV60787987; called by muse, mutect2, varscan2
- TFE3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as rs782500227, COSV59946774; called by muse, mutect2, varscan2
- TGIF1 | c.462C>A p.C154* (on ENST00000330513 / NM_001374396.1; = p.C174* on NM_003244.4) | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV57907476; called by muse, mutect2, varscan2
- TMEM74 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs141941950; called by muse, mutect2, varscan2
- TTC12 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV100133045; called by muse, mutect2, varscan2
- TXLNG | c.1005A>C p.E335D | Missense Mutation (SNP) | VAF 74/326 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.679); catalogued as COSV66329732; called by muse, mutect2, varscan2
- UBQLN2 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 19/114 reads (17%) | catalogued as COSV57739465; called by muse, mutect2, varscan2
- UGT3A2 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 36/193 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.59); catalogued as rs138640717; called by muse, mutect2, varscan2
- VIPR2 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1157096085, COSV51106132; called by muse, mutect2, varscan2
- WDR17 | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762164967, COSV54572833; called by muse, mutect2, varscan2
- ZNF417 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.293); catalogued as COSV100364187; called by muse, varscan2
- ZNF804A | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56446660; called by muse, mutect2, varscan2
- ZNF804A | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 35/259 reads (14%) | catalogued as rs772974941, COSV56437401, COSV56474195; called by muse, mutect2, varscan2
- ZNF816 | c.212T>C p.M71T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.22); catalogued as rs765736659, COSV54411112; called by muse, mutect2, varscan2
- ARID1A | c.4689dup p.M1564Hfs*8 | Frame Shift Ins (INS) | VAF 26/153 reads (17%) | called by mutect2, pindel, varscan2
- GLYR1 | c.1620_1627del p.D541Yfs*183 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- HLA-B | c.635_636del p.H212Rfs*8 | Frame Shift Del (DEL) | VAF 40/214 reads (19%) | called by pindel, varscan2
- LRP1B | c.9360_9366del p.Y3120* | Frame Shift Del (DEL) | VAF 20/157 reads (13%) | called by mutect2, pindel, varscan2
- PRAMEF8 | c.1085A>G p.D362G | Missense Mutation (SNP) | VAF 26/327 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSMA5 | c.552_553insAAT p.V184_Y185insN | In Frame Ins (INS) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- SOX9 | c.1246del p.Q416Nfs*54 | Frame Shift Del (DEL) | VAF 55/134 reads (41%) | called by mutect2, pindel, varscan2
- TBC1D9 | c.3630del p.I1211Sfs*11 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | called by mutect2, pindel, varscan2
- TFAP2B | c.219del p.Y74Tfs*22 | Frame Shift Del (DEL) | VAF 33/201 reads (16%) | called by mutect2, pindel, varscan2
- APBA2 | c.24C>T p.S8= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs770399185, COSV68790732; called by muse, mutect2, varscan2
- ARSB | c.1188C>T p.D396= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV53723463; called by muse, mutect2, varscan2
- C19orf57 | c.1320G>A p.P440= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs761219639, COSV60968151; called by muse, mutect2, varscan2
- C2CD6 | c.1236G>T p.L412= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV53794223; called by muse, mutect2, varscan2
- CCDC88A | c.1329C>T p.S443= | Silent (SNP) | VAF 35/195 reads (18%) | catalogued as rs1447080799, COSV55060907, COSV55068061; called by muse, mutect2, varscan2
- CDH9 | c.1992C>T p.G664= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as rs770202136, COSV50276177, COSV99162980; called by muse, mutect2, varscan2
- CREBBP | c.3507C>T p.R1169= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV52122014; called by muse, mutect2, varscan2
- FAT4 | c.12342C>T p.I4114= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV58682524; called by muse, mutect2, varscan2
- IRAK1 | c.1626G>A p.P542= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs150089165, COSV64110769; called by muse, mutect2, varscan2
- IRAK2 | c.270C>T p.I90= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV56530934; called by muse, mutect2, varscan2
- KIAA1549L | c.3045C>T p.T1015= (on ENST00000321505; = p.T1312= on NM_012194.3) | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs763535300, COSV55772887; called by mutect2, varscan2
- KIAA1549L | c.4515C>T p.Y1505= (on ENST00000321505; = p.Y1802= on NM_012194.3) | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs551823874, COSV58587339; called by muse, mutect2, varscan2
- KIR2DL4 | c.390C>T p.H130= (on ENST00000396284; = p.H91= on NM_001080770.2) | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs763756662, COSV100610566; called by muse, mutect2, varscan2
- LMBR1L | c.978C>T p.I326= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs943663626, COSV57267537, COSV57268239; called by muse, mutect2, varscan2
- LRP1B | c.13794G>T p.V4598= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV67212933; called by muse, mutect2, varscan2
- MFSD11 | c.33C>T p.I11= | Silent (SNP) | VAF 65/129 reads (50%) | catalogued as COSV100333730; called by muse, mutect2, varscan2
- MYO16 | c.969C>G p.T323= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV51791213, COSV99194342; called by muse, mutect2, varscan2
- PCDH19 | c.642C>T p.G214= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV55261955; called by muse, mutect2
- PKP2 | c.1137C>T p.H379= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs754927123, COSV50729942; called by muse, mutect2, varscan2
- QTRT2 | c.717C>T p.V239= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV55559892; called by muse, mutect2, varscan2
- RNF31 | c.405C>T p.P135= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV53759341; called by muse, mutect2, varscan2
- SIPA1L3 | c.1302C>T p.I434= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs368559210; called by muse, mutect2, varscan2
- THEMIS | c.1071C>T p.I357= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as rs146173025, COSV64069646; called by muse, mutect2, varscan2
- TKT | c.1260C>T p.S420= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV56244223; called by muse, mutect2, varscan2
- TTN | c.74622C>T p.G24874= (on ENST00000591111; = p.G17450= on NM_003319.4) | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs761713195, COSV60020642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.6090C>G p.L2030= (on ENST00000591111; = p.L1984= on NM_003319.4) | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV60020685, COSV60375886; called by muse, mutect2, varscan2
- UBE3C | c.1125C>T p.A375= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs746804527, COSV61952858; called by muse, mutect2, varscan2
- ZSCAN10 | c.1146C>T p.C382= (on ENST00000252463; = p.C437= on NM_032805.3) | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV52969316, COSV99374295; called by muse, mutect2, varscan2
- GNA12 | c.310-19224G>T | Intron (SNP) | VAF 18/59 reads (31%) | catalogued as COSV99282558; called by muse, mutect2, varscan2
